Gene-level copy-number profile of tumor specimen TCGA-EK-A2IR-01A from TCGA case TCGA-EK-A2IR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 48.1 years (17,581 days).
Specimen TCGA-EK-A2IR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.24bae48c-27f8-4331-b473-d791a2470ef4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2IR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/89f44dec-b234-4642-a202-0e07c42a1c4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 491; copy number 1: 11,829; copy number 2: 34,298; copy number 3: 9,525; copy number 4: 3,442; copy number 5: 505; copy number 6: 21; copy number 8: 71; copy number 12: 57; copy number 49: 14; copy number 71: 8.

Homozygous deletions (total copy number 0; autosomes only): 491 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,969,119–75,785,583, 295 genes (within-gene range 0–8) (broad region; genes not listed).
- chr4:53,286–270,175, 8 genes: ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5.
- chr8:38,225,218–38,275,558, 2 genes (within-gene range 0–6): DDHD2, PLPP5.
- chr8:38,275,888–38,276,680, 1 gene: AC087362.2.
- chr10:6,245,731–6,245,831, 1 gene: Y_RNA.
- chr10:7,096,216–7,413,467, 5 genes: LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1.
- chr10:113,550,837–116,477,957, 43 genes (within-gene range 0–1): HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1, NTAN1P1, GFRA1, AC012470.1, CCDC172, SNRPGP6, PNLIPRP3, HMGB3P8.
- chr11:112,393,118–118,482,737, 136 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 676 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 2–8): AC244205.1.
- chr2:88,857,161–89,990,221, 70 genes, copy number 8 (broad region; genes not listed).
- chr3:179,396,088–198,222,513, 441 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:38,176,533–38,231,695, 3 genes, copy number 6: BAG4, AC084024.2, AC084024.4.
- chr8:38,269,704–38,382,272, 1 gene, copy number 71 (within-gene range 0–71): NSD3.
- chr8:38,335,981–38,468,834, 7 genes, copy number 71 (within-gene range 71–90): AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr8:41,426,655–41,650,817, 11 genes, copy number 49: SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3.
- chr8:41,660,441–41,665,566, 3 genes, copy number 49: MIR486-1, MIR486-2, AC113133.1.
- chr8:41,929,479–43,674,591, 57 genes, copy number 12: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr10:83,067,962–84,294,659, 18 genes, copy number 6 (within-gene range 1–6): RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858.
- chr22:16,405,330–17,628,749, 64 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,309. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
